Somatic mutation profile of tumor specimen MP2PRT-PANVKF-TMP1-A (aliquot MP2PRT-PANVKF-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PANVKF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.7 years (2,440 days).
Specimen MP2PRT-PANVKF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d9bfd2c9-b207-4767-a4f0-057b9c0c99d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANVKF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANVKF-NB1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95fdb3bc-e062-44c6-8e83-c4291d4d0c75

The open-access MAF lists 24 somatic variants for this specimen: 17 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 6, Intron 1, In Frame Del 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 30/417 reads (7%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2
- ACE | c.1340C>T p.T447M | Missense Mutation (SNP) | VAF 93/311 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.071); catalogued as rs746314800, COSV52012716; called by muse, mutect2, varscan2
- ADAM12 | c.1795G>A p.V599I | Missense Mutation (SNP) | VAF 74/469 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs763997822; called by muse, mutect2, varscan2
- ATF7IP | c.1706G>C p.R569P | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53774760, COSV53777006; called by muse, mutect2, varscan2
- ITPRIPL2 | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 38/732 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs1230887539; called by muse, mutect2
- LRRC72 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 110/260 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs145598091, COSV69130441; called by muse, mutect2, varscan2
- PTPN13 | c.6223G>A p.E2075K (on ENST00000411767 / NM_080683.3; = p.E2056K on NM_006264.3) | Missense Mutation (SNP) | VAF 25/318 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs764940015, COSV57403359; called by muse, mutect2
- TCF25 | c.393A>C p.K131N | Missense Mutation (SNP) | VAF 118/312 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.132); catalogued as rs772673723, COSV54524826; called by muse, mutect2, varscan2
- ATF7IP | c.1606C>T p.Q536* | Nonsense Mutation (SNP) | VAF 12/259 reads (5%) | called by muse, mutect2
- IGHG2 | c.188A>G p.Y63C | Missense Mutation (SNP) | VAF 67/676 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOBOX | c.1261T>C p.S421P | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NXF1 | c.637A>C p.K213Q | Missense Mutation (SNP) | VAF 55/261 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- OR5T3 | c.392C>A p.A131D | Missense Mutation (SNP) | VAF 206/519 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SDHAF4 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 24/239 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC5A6 | c.1883G>A p.C628Y | Missense Mutation (SNP) | VAF 44/444 reads (10%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); called by muse, mutect2
- TEX10 | c.64_66del p.K22del | In Frame Del (DEL) | VAF 45/200 reads (23%) | called by pindel, varscan2
- UBA2 | c.151_155del p.T51* | Frame Shift Del (DEL) | VAF 19/159 reads (12%) | called by pindel*, varscan2
- ADGRG6 | c.342T>A p.T114= | Silent (SNP) | VAF 31/413 reads (8%) | called by muse, mutect2
- COL4A1 | c.1884C>A p.S628= | Silent (SNP) | VAF 29/381 reads (8%) | called by muse, mutect2
- EPB41L2 | c.1986G>A p.P662= | Silent (SNP) | VAF 125/440 reads (28%) | catalogued as rs376910072; called by muse, mutect2, varscan2
- SHOX | c.708G>A p.A236= | Silent (SNP) | VAF 100/1046 reads (10%) | called by muse, mutect2
- TAF1L | c.5031G>A p.T1677= | Silent (SNP) | VAF 78/331 reads (24%) | catalogued as rs763903524, COSV54264307; called by muse, mutect2, varscan2
- TEX15 | c.3672C>T p.D1224= (on ENST00000256246; = p.D1607= on NM_001350162.2) | Silent (SNP) | VAF 66/192 reads (34%) | catalogued as rs372369352; called by muse, mutect2
- OR2S1P | n.273-9193G>A | Intron (SNP) | VAF 115/266 reads (43%) | catalogued as rs775832362; called by muse, mutect2, varscan2
